Somatic mutation profile of tumor specimen 0DMKL0 from CCDI case PBBZMC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 10.0 years (3,667 days).
Specimen 0DMKL0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 753a91e8-b676-4762-b9a2-3df8f9e0e95a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMKKG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/812b012e-65c3-47a0-aef9-2955f553fcb6

The open-access MAF lists 69 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 16, 3'UTR 6, Intron 2, 5'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8orf34 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 232/738 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs548341726, COSV57416688; called by muse, varscan2
- CALB1 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 219/809 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV99618099; called by muse, varscan2
- CES1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs750466071; called by muse, varscan2
- CH25H | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 128/438 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs763896674, CM148043; called by muse, varscan2
- CLCN5 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 146/843 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs151340628, CM970316, COSV56582155; called by muse, varscan2
- CYP24A1 | c.337T>C p.C113R | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as rs745661961; called by muse, varscan2
- ERCC6L | c.2969C>G p.A990G | Missense Mutation (SNP) | VAF 172/950 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs759679045; called by muse, varscan2
- FBN1 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 106/344 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1262119022, COSV100356463; called by muse, varscan2
- HIVEP1 | c.6821C>T p.P2274L | Missense Mutation (SNP) | VAF 139/423 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs770790070; called by muse, varscan2
- HUWE1 | c.5680C>T p.R1894C | Missense Mutation (SNP) | VAF 426/708 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99473254; called by muse, varscan2
- IGSF3 | c.1307C>T p.T436M (on ENST00000369486 / NM_001007237.3; = p.T456M on NM_001542.4) | Missense Mutation (SNP) | VAF 112/282 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.293); catalogued as rs61786578, COSV59586296; called by muse, varscan2
- LONRF2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.115); catalogued as rs777504163, COSV66541725; called by muse, varscan2
- MAGEB2 | c.554A>T p.D185V | Missense Mutation (SNP) | VAF 108/582 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV66780992; called by muse, varscan2
- MYCBP2 | c.5822C>T p.P1941L (on ENST00000357337; = p.P1979L on NM_015057.5) | Missense Mutation (SNP) | VAF 160/928 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1465197927; called by muse, varscan2
- NF1 | c.1586T>C p.L529P | Missense Mutation (SNP) | VAF 220/510 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM143324, COSV62216371; called by muse, varscan2
- OSTN | c.171C>A p.D57E | Missense Mutation (SNP) | VAF 151/424 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs759726596; called by muse, varscan2
- PRRT4 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as rs1247127776, COSV71054802; called by muse, varscan2
- ROR2 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 125/310 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs138087167, COSV65217033, COSV65217045; called by muse, varscan2
- SAP30BP | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as rs754133880, COSV53129950; called by muse, varscan2
- TRPC7 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs752304356, COSV61460074; called by muse, varscan2
- UBE3C | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 122/788 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs770697534; called by muse, varscan2
- ZFR2 | c.1490G>C p.R497P | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs780295865; called by muse, varscan2
- ZNF800 | c.1847C>G p.S616C | Missense Mutation (SNP) | VAF 226/1308 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56174119; called by muse, varscan2
- ADAD2 | c.712G>T p.A238S (on ENST00000315906 / NM_001145400.2; = p.A310S on NM_139174.4) | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- ANK2 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 138/412 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARHGEF28 | c.1322C>A p.A441D | Missense Mutation (SNP) | VAF 94/376 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, varscan2
- ATP11C | c.2504G>A p.G835D | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CENPE | c.7009G>C p.E2337Q | Missense Mutation (SNP) | VAF 81/432 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, varscan2
- CHM | c.1229A>T p.D410V | Missense Mutation (SNP) | VAF 116/643 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- COL5A1 | c.4751G>C p.R1584P | Missense Mutation (SNP) | VAF 94/262 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- DIPK2B | c.559C>G p.R187G | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, varscan2
- DSC2 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, varscan2
- ELFN1 | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, varscan2
- FZD1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); called by muse, varscan2
- HCFC1 | c.5651A>C p.K1884T | Missense Mutation (SNP) | VAF 88/614 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MADCAM1 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, varscan2
- NFX1 | c.1567T>C p.C523R | Missense Mutation (SNP) | VAF 132/300 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OTUD1 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); called by muse, varscan2
- PCDHA11 | c.697T>A p.L233M | Missense Mutation (SNP) | VAF 132/469 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.903); called by muse, varscan2
- SHC3 | c.1600A>G p.T534A | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, varscan2
- TMEM232 | c.1835C>A p.A612E | Missense Mutation (SNP) | VAF 212/532 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.028); called by muse, varscan2
- ZNF366 | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 52/474 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, varscan2
- CAPS2 | c.555T>C p.D185= | Silent (SNP) | VAF 192/591 reads (32%) | catalogued as rs1372907102; called by muse, varscan2
- CARD11 | c.3357G>A p.T1119= | Silent (SNP) | VAF 177/417 reads (42%) | catalogued as rs374463734; called by muse, varscan2
- COL16A1 | c.2262C>T p.G754= | Silent (SNP) | VAF 69/166 reads (42%) | catalogued as rs762839880, COSV54710074; called by muse, varscan2
- DDX11 | c.1275C>T p.Y425= | Silent (SNP) | VAF 54/329 reads (16%) | catalogued as rs1251824258, COSV52506114; called by muse, varscan2
- DHRS3 | c.417C>T p.A139= | Silent (SNP) | VAF 102/215 reads (47%) | called by muse, varscan2
- DNAH5 | c.9213C>T p.H3071= | Silent (SNP) | VAF 120/312 reads (38%) | catalogued as rs563907105, COSV54216067; ClinVar: likely benign; called by muse, varscan2
- GARS1 | c.361C>A p.R121= | Silent (SNP) | VAF 222/1166 reads (19%) | catalogued as COSV66827793; called by muse, varscan2
- HOXA4 | c.738C>T p.I246= | Silent (SNP) | VAF 125/730 reads (17%) | called by muse, varscan2
- LAMB4 | c.3669C>T p.N1223= | Silent (SNP) | VAF 140/1010 reads (14%) | catalogued as rs373290819; called by muse, varscan2
- PCOLCE2 | c.1059C>A p.G353= | Silent (SNP) | VAF 52/456 reads (11%) | called by muse, varscan2
- PIGO | c.2091C>A p.P697= | Silent (SNP) | VAF 74/247 reads (30%) | called by muse, varscan2
- PRRT3 | c.1272G>A p.T424= | Silent (SNP) | VAF 43/115 reads (37%) | called by muse, varscan2
- SLC2A6 | c.322C>A p.R108= | Silent (SNP) | VAF 72/194 reads (37%) | catalogued as COSV100902786; called by muse, varscan2
- SLC9A3 | c.411C>T p.F137= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as rs754348626; called by muse, varscan2
- TACC2 | c.2382G>A p.T794= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as rs746247635, COSV100552091, COSV100554501; called by muse, varscan2
- TBC1D13 | c.1029C>T p.A343= | Silent (SNP) | VAF 34/291 reads (12%) | catalogued as rs765024773, COSV56355158, COSV99804669; called by muse, varscan2
- AK2 | c.*2399C>T | 3'UTR (SNP) | VAF 40/386 reads (10%) | catalogued as rs757543230; called by muse, varscan2
- CASP4 | c.782-22C>A | Intron (SNP) | VAF 84/161 reads (52%) | called by muse, varscan2
- HADH | c.710-744T>A | Intron (SNP) | VAF 69/239 reads (29%) | called by muse, varscan2
- IFI16 | c.*53A>C | 3'UTR (SNP) | VAF 155/246 reads (63%) | called by muse, varscan2
- LTF | c.*5G>A | 3'UTR (SNP) | VAF 136/354 reads (38%) | catalogued as rs764625773, COSV99208513; called by muse, varscan2
- MCU | c.*26C>A | 3'UTR (SNP) | VAF 82/461 reads (18%) | catalogued as COSV100849217; called by muse, varscan2
- MUC19 | n.9167G>T | RNA (SNP) | VAF 82/100 reads (82%) | called by muse, varscan2
- PRPS2 | c.-2C>A | 5'UTR (SNP) | VAF 160/664 reads (24%) | called by muse, varscan2
- RGCC | c.*57A>G | 3'UTR (SNP) | VAF 124/740 reads (17%) | called by muse, varscan2
- SPANXD | c.-48C>G | 5'UTR (SNP) | VAF 76/320 reads (24%) | called by muse, varscan2
- TULP3 | c.*1355C>T | 3'UTR (SNP) | VAF 7/49 reads (14%) | catalogued as rs1035269253; called by muse, varscan2
